TARGET case TARGET-20-D7-Myeloid-mock3 — Acute Myeloid Leukemia (TARGET-AML)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Myeloid Leukemias; Primary site: Hematopoietic and reticuloendothelial systems.
https://portal.gdc.cancer.gov/cases/a0c11ebf-d703-4f5c-8280-874c42bf91c4

Biospecimens (1 sample)
- Sample TARGET-20-D7-Myeloid-mock3-85: Sample type: Next Generation Cancer Model; Tissue type: Normal.
